Somatic mutation profile of tumor specimen TARGET-20-PARIEG-09A (aliquot TARGET-20-PARIEG-09A-01D) from TARGET case TARGET-20-PARIEG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.4 years (4,881 days).
Specimen TARGET-20-PARIEG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f4ec3e7-ab91-4c63-b84f-fc626557f60d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARIEG-14A (Bone Marrow Normal), aliquot TARGET-20-PARIEG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00129ada-3434-4334-a881-3aed765c8765

The open-access MAF lists 22 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 3, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 69/584 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 103/439 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FAXDC2 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 83/187 reads (44%) | catalogued as rs769797713, COSV58172365; called by muse, mutect2, varscan2
- FGF5 | c.63C>A p.H21Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100427898; called by muse, varscan2
- GATA2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141458, COSV62002954; called by muse, mutect2, varscan2
- IQCA1 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 70/176 reads (40%) | catalogued as rs901228069, COSV54502587; called by muse, mutect2, varscan2
- MUC5B | c.9596C>T p.T3199M | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs371217175; called by muse, mutect2
- MYH4 | c.1305C>A p.Y435* | Nonsense Mutation (SNP) | VAF 60/267 reads (22%) | catalogued as COSV55116378; called by muse, mutect2, varscan2
- OR5AR1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs758374441, COSV57254483; called by muse, mutect2
- PLEKHG3 | c.860T>A p.I287N (on ENST00000394691; = p.I343N on NM_001308147.2) | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99906847; called by muse, mutect2, varscan2
- RASSF5 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs900661125; called by muse, mutect2
- TAF1L | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 42/716 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs966161973; called by muse, mutect2
- ZNF157 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs985545308; called by muse, mutect2, varscan2
- ETV6 | c.328+1_328+3del p.X110_splice | Splice Site (DEL) | VAF 46/125 reads (37%) | called by mutect2, pindel, varscan2
- KAT6A | c.3424dup p.T1142Nfs*33 | Frame Shift Ins (INS) | VAF 28/206 reads (14%) | called by mutect2, pindel, varscan2
- MEAF6 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 76/357 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MTM1 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- SF3A1 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2
- CES4A | c.750G>A p.A250= | Silent (SNP) | VAF 112/243 reads (46%) | catalogued as rs781591841; called by muse, mutect2, varscan2
- LIPN | c.1038C>T p.L346= | Silent (SNP) | VAF 147/300 reads (49%) | catalogued as rs771416939, COSV101356201, COSV101356239; called by muse, mutect2, varscan2
- RAPH1 | c.795G>A p.E265= (on ENST00000319170 / NM_213589.3; = p.E317= on NM_203365.4) | Silent (SNP) | VAF 220/592 reads (37%) | catalogued as COSV57357143; called by muse, mutect2, varscan2
- TRIM64B | c.162G>A p.S54= | Silent (SNP) | VAF 19/287 reads (7%) | catalogued as rs775650127; called by muse, mutect2
